Somatic mutation profile of tumor specimen TCGA-A6-6652-01A (aliquot TCGA-A6-6652-01A-11D-1771-10) from TCGA case TCGA-A6-6652, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IVA; Age at diagnosis: 59.2 years (21,638 days).
Specimen TCGA-A6-6652-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c7e53f0-24d0-4c33-b3c2-fe1890df2294.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-6652-10A (Blood Derived Normal), aliquot TCGA-A6-6652-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5926dcb2-725e-4a44-b75b-f1a22450ec7e

The open-access MAF lists 91 somatic variants for this specimen: 66 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 23, Frame Shift Del 6, Nonsense Mutation 4, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5428G>A p.D1810N | Missense Mutation (SNP) | VAF 69/96 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775912475, COSV58615443, COSV58615662, COSV58615890; called by muse, mutect2, varscan2
- TP53 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 40/51 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193920817, COSV52660939, COSV52789715, COSV53470581; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.9817T>A p.L3273M | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71289914, COSV71291341; called by muse, mutect2, varscan2
- AFF1 | c.3109G>A p.D1037N | Missense Mutation (SNP) | VAF 98/237 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as COSV57120891, COSV57123594; called by muse, mutect2, varscan2
- ANKRD13C | c.1385G>T p.G462V | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV52032440, COSV52035210; called by muse, mutect2, varscan2
- ANKRD50 | c.1703G>A p.G568E | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.41); catalogued as COSV101538953; called by muse, mutect2, varscan2
- APC | c.509_512del p.D170Vfs*4 | Frame Shift Del (DEL) | VAF 28/106 reads (26%) | catalogued as rs387906231; called by pindel, varscan2
- APC | c.3842C>G p.S1281* | Nonsense Mutation (SNP) | VAF 40/99 reads (40%) | catalogued as CM106371, COSV57326196, COSV57330499; called by muse, mutect2, varscan2
- ARSB | c.920C>A p.A307E | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.139); catalogued as COSV53725201; called by muse, mutect2, varscan2
- BEND3 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.1); catalogued as rs781852720, COSV64681369; called by muse, mutect2, varscan2
- C2orf16 | c.3046C>T p.P1016S | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.188); catalogued as COSV62676402; called by muse, mutect2, varscan2
- CAD | c.3812T>A p.L1271* | Nonsense Mutation (SNP) | VAF 8/116 reads (7%) | catalogued as COSV99254996; called by muse, mutect2
- CDH9 | c.2157A>T p.R719S | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50262886, COSV50303490; called by muse, mutect2, varscan2
- CLUH | c.2480C>T p.T827M (on ENST00000435359; = p.T866M on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/100 reads (78%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs769848334, COSV70929020; called by muse, mutect2, varscan2
- CPAMD8 | c.574G>A p.V192M (on ENST00000651564; = p.V145M on NM_015692.5) | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99359352; called by muse, mutect2, varscan2
- CPLANE2 | c.300G>T p.K100N | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV65056980; called by muse, mutect2, varscan2
- DHTKD1 | c.1361C>G p.A454G | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV53804323; called by muse, mutect2, varscan2
- DIRAS1 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as rs1435065344, COSV60215923; called by muse, mutect2, varscan2
- EXTL1 | c.1856G>A p.G619E | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV65332858; called by muse, mutect2, varscan2
- FAM9B | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 44/52 reads (85%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.961); catalogued as COSV59119675; called by muse, mutect2, varscan2
- FCRL3 | c.553G>T p.V185F | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as COSV63842488; called by muse, mutect2
- FPR2 | c.907G>A p.V303I | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs373596683; called by muse, mutect2, varscan2
- FUT9 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56145360, COSV56149256; called by muse, mutect2, varscan2
- GCM2 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs765918099, COSV101069522; called by muse, mutect2, varscan2
- GZF1 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1482769865, COSV57636585; called by muse, mutect2, varscan2
- HEXIM2 | c.170A>T p.D57V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.605); catalogued as COSV56236602; called by muse, mutect2, varscan2
- INTS13 | c.1838A>C p.E613A | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.112); catalogued as COSV53904881, COSV99677360; called by muse, mutect2, varscan2
- IRX1 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs777288883, COSV57360192; called by muse, mutect2, varscan2
- ITIH6 | c.2224G>A p.G742S | Missense Mutation (SNP) | VAF 53/58 reads (91%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370043675, COSV54490286; called by muse, mutect2, varscan2
- KCNH8 | c.2380T>G p.L794V | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.148); catalogued as rs1200200106, COSV60460214, COSV60478079; called by muse, mutect2, varscan2
- LRRC56 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs778415386, COSV54240153, COSV54242532; called by muse, mutect2, varscan2
- LRRIQ1 | c.335A>G p.K112R | Missense Mutation (SNP) | VAF 76/188 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as COSV67813259; called by muse, mutect2, varscan2
- MCHR2 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs201793988, COSV56001620; called by muse, mutect2, varscan2
- MFSD14A | c.1141T>C p.C381R | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99790817; called by muse, mutect2, varscan2
- MUC5B | c.10900G>A p.V3634M | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373098262; called by mutect2, varscan2
- MYH9 | c.3619C>T p.Q1207* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | catalogued as COSV53387907; called by muse, mutect2
- MYO15A | c.7762C>T p.R2588W | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs778098806, COSV52755357; called by muse, mutect2, varscan2
- MYO16 | c.4918G>A p.V1640M | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.475); catalogued as rs753195434, COSV62752053; called by muse, mutect2, varscan2
- NAV3 | c.6871A>G p.K2291E (on ENST00000397909 / NM_001024383.2; = p.K2269E on NM_014903.6) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.955); catalogued as rs1187441915, COSV57087470; called by muse, mutect2, varscan2
- NKX2-2 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.445); catalogued as rs759316509, COSV65819781; called by muse, mutect2, varscan2
- OR2W3 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 57/101 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.425); catalogued as rs148268889; called by muse, mutect2, varscan2
- OR56A1 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.042); catalogued as COSV57362985; called by muse, mutect2, varscan2
- OR56B4 | c.204G>T p.L68F | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57204078; called by muse, mutect2, varscan2
- OR6F1 | c.336C>A p.Y112* | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as COSV57468228; called by muse, mutect2, varscan2
- PDZRN3 | c.2130G>T p.Q710H | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV55204017; called by muse, mutect2, varscan2
- PI4KA | c.5030C>T p.A1677V | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs754844315, COSV55413791; called by muse, mutect2, varscan2
- PKD1L1 | c.7079C>T p.P2360L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs982895686, COSV51843093; called by muse, mutect2, varscan2
- PLXNA4 | c.2898G>T p.M966I | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs996563664, COSV58134441; called by muse, mutect2, varscan2
- RETREG3 | c.1088G>T p.G363V | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV53817547; called by muse, mutect2, varscan2
- RNF17 | c.4234G>A p.E1412K | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV99693124; called by muse, mutect2, varscan2
- SGMS2 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1019997577, COSV62989325; called by muse, mutect2, varscan2
- SORCS1 | c.2341G>A p.V781I | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as rs370679881, COSV53857213; called by muse, varscan2
- SOX9 | c.872del p.V291Afs*92 | Frame Shift Del (DEL) | VAF 25/53 reads (47%) | catalogued as COSV55425137; called by mutect2, pindel, varscan2
- SYT5 | c.531C>G p.F177L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62830593; called by muse, mutect2, varscan2
- TAF1L | c.1947G>T p.Q649H | Missense Mutation (SNP) | VAF 98/234 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV54263526; called by muse, varscan2
- TANC1 | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.089); catalogued as rs768225368, COSV55089746, COSV99069570; called by muse, mutect2, varscan2
- TRPS1 | c.2402G>A p.R801Q (on ENST00000220888 / NM_001330599.2; = p.R814Q on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.728); catalogued as rs146506752, CM051657, COSV55246583; called by muse, mutect2, varscan2
- TTN | c.41486G>A p.R13829H (on ENST00000591111; = p.R6405H on NM_003319.4) | Missense Mutation (SNP) | VAF 56/99 reads (57%) | PolyPhen probably damaging (0.998); catalogued as rs769044716, COSV59945364, COSV60027324; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR48 | c.83A>G p.Y28C | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV56532568; called by muse, mutect2, varscan2
- ZMYND12 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs139202265; called by muse, mutect2, varscan2
- HERPUD1 | c.855del p.S286Pfs*2 | Frame Shift Del (DEL) | VAF 76/202 reads (38%) | called by mutect2, pindel, varscan2
- IGHG1 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 58/90 reads (64%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RAE1 | c.743del p.P248Rfs*29 | Frame Shift Del (DEL) | VAF 24/113 reads (21%) | called by mutect2, pindel, varscan2
- RPL13 | c.35C>A p.P12H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.907); called by muse, varscan2
- SPATC1 | c.1030del p.Q344Rfs*72 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- TENM1 | c.3497del p.P1166Qfs*6 | Frame Shift Del (DEL) | VAF 67/109 reads (61%) | called by mutect2, pindel, varscan2
- ARFGAP2 | c.261T>C p.N87= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs1245765439, COSV100096337; called by muse, mutect2, varscan2
- CABP2 | c.408C>T p.F136= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs773079612, COSV53708820; called by muse, mutect2, varscan2
- CCDC105 | c.1245C>T p.L415= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV52963916, COSV99479950; called by muse, mutect2, varscan2
- COQ10B | c.90C>T p.P30= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs748686379, COSV55836527, COSV55837164; called by muse, mutect2, varscan2
- DGKK | c.2964T>C p.H988= | Silent (SNP) | VAF 36/41 reads (88%) | catalogued as COSV101052987; called by muse, mutect2, varscan2
- GHSR | c.273C>T p.L91= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as COSV99576916; called by muse, mutect2, varscan2
- GRID2 | c.277C>T p.L93= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV56219038; called by muse, mutect2, varscan2
- HTT | c.1911G>A p.R637= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as COSV61863816; called by muse, mutect2, varscan2
- IRF7 | c.1053G>A p.P351= (on ENST00000397566; = p.P338= on NM_001572.5) | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs760052779, COSV52757240; called by muse, mutect2, varscan2
- KCNS3 | c.1389C>T p.S463= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as rs776349440, COSV58405068; called by muse, mutect2, varscan2
- MAPRE3 | c.816G>A p.E272= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV51867648; called by muse, mutect2, varscan2
- MEF2D | c.123C>T p.C41= | Silent (SNP) | VAF 70/241 reads (29%) | catalogued as rs756430794, COSV61729074; called by muse, mutect2, varscan2
- MGLL | c.552C>G p.L184= (on ENST00000398104 / NM_001003794.2; = p.L194= on NM_007283.6) | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as rs538109563, COSV54026379; called by muse, mutect2, varscan2
- NPAS3 | c.1470C>T p.S490= (on ENST00000356141 / NM_001164749.2; = p.S458= on NM_022123.3) | Silent (SNP) | VAF 13/16 reads (81%) | catalogued as rs374909389; called by muse, mutect2, varscan2
- NRXN1 | c.1209A>G p.E403= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV58462031; called by muse, mutect2, varscan2
- OR52H1 | c.495G>T p.L165= (on ENST00000322653; = p.L171= on NM_001005289.1) | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV59505587; called by muse, mutect2, varscan2
- RAB6C | c.577C>T p.L193= | Silent (SNP) | VAF 41/1175 reads (3%) | called by muse, mutect2
- SEMA5B | c.924C>T p.H308= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs371727436, COSV52100693; called by muse, mutect2, varscan2
- SMTNL1 | c.1170C>T p.Y390= (on ENST00000399154; = p.Y427= on NM_001105565.2) | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs570413222, COSV67699627; called by muse, mutect2, varscan2
- SYNE1 | c.17841A>G p.L5947= (on ENST00000367255 / NM_182961.4; = p.L5876= on NM_033071.3) | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs143490673; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TMEM104 | c.1266G>T p.V422= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV59110014; called by muse, mutect2, varscan2
- TTYH1 | c.252G>A p.S84= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs768683157, COSV56610835; called by muse, mutect2, varscan2
- XYLT1 | c.1830G>A p.G610= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as rs746316067, COSV54487114; called by muse, mutect2, varscan2
- RRP7A | c.*3817G>C | 3'UTR (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- SSPOP | n.4425G>A | RNA (SNP) | VAF 17/71 reads (24%) | catalogued as rs1236338537, COSV50486640; called by muse, mutect2, varscan2
